Somatic mutation profile of tumor specimen HCM-BROD-0596-C43-06A (aliquot HCM-BROD-0596-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0596-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.7 years (25,087 days).
Specimen HCM-BROD-0596-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0580ed5-8598-4059-8f38-aa583cd1f992.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0596-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0596-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ad70cc-53f8-409e-adb1-c53eb99a0585

The open-access MAF lists 2,870 somatic variants for this specimen: 1,764 protein-altering or splice-affecting, 990 silent, 116 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,603, Silent 990, Nonsense Mutation 108, Intron 62, Splice Region 21, 5'Flank 14, 3'UTR 14, RNA 12, Splice Site 11, Frame Shift Del 8, 3'Flank 7, 5'UTR 6.

Variants (750 of 2,870; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 150/270 reads (56%) | catalogued as rs1411638309, COSV56852422; ClinVar: likely pathogenic; called by muse, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 170/282 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 184/417 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1554395411; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3301G>A p.G1101R | Missense Mutation (SNP) | VAF 157/534 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779439, CM1412704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 363/599 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852416, CM910128, COSV100812232; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFAP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 193/405 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs57661783, CM051052; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 209/468 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 420/696 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917758, CM081303, COSV54240842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMUT | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 65/485 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs564069299, CM990882, COSV51272456, COSV51275106, COSV51281714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX11B | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 390/812 reads (48%) | catalogued as rs781984979, COSV65197176; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 191/418 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs193922770, CM971325, COSV62102500; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- AADACL2 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 202/502 reads (40%) | catalogued as COSV62930159; called by muse, mutect2, varscan2
- AADACL3 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 333/681 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60200529; called by muse, mutect2
- AADACL4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 177/514 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs375635678; called by muse, mutect2, varscan2
- AC008397.2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 191/533 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53208262; called by muse, mutect2, varscan2
- AC099489.1 | c.5635G>A p.G1879S | Missense Mutation (SNP) | VAF 98/437 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.125); catalogued as rs1294616792; called by muse, mutect2
- AC119396.1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 227/400 reads (57%) | catalogued as rs1006176645; called by muse, mutect2, varscan2
- AC136428.1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 186/292 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs766270124, COSV101434973; called by muse, mutect2, varscan2
- ACSL6 | c.1453C>T p.P485S (on ENST00000379240; = p.P510S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/381 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as rs867535797; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 106/174 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM2A | c.1679G>A p.R560Q (on ENST00000219054; = p.R481Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 201/323 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148142047; called by muse, mutect2, varscan2
- ACTA2 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 161/176 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM118490; called by muse, mutect2, varscan2
- ACTR1A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 258/293 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64024400; called by muse, mutect2, varscan2
- ACTRT2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 287/617 reads (47%) | catalogued as rs867646845, COSV65759371; called by muse, varscan2
- ADAM20 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 215/416 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99833399; called by muse, mutect2, varscan2
- ADAM7 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751999467, COSV51534385; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 219/516 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADAM7 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 242/495 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV51535166; called by muse, mutect2, varscan2
- ADAMTS18 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 196/305 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs865936548, COSV51419356; called by muse, mutect2, varscan2
- ADAMTS2 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 367/950 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV52371211; called by muse, mutect2, varscan2
- ADAMTS20 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67139155, COSV99061796; called by muse, mutect2, varscan2
- ADAMTS20 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270702920, COSV67129732; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3578G>A p.S1193N | Missense Mutation (SNP) | VAF 311/669 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV65890689; called by muse, mutect2, varscan2
- ADCY1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV52031960; called by muse, mutect2, varscan2
- ADCY8 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 233/494 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99650680; called by muse, mutect2, varscan2
- ADCY8 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 254/563 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV53900356; called by muse, mutect2, varscan2
- ADCYAP1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV52486068; called by muse, mutect2
- ADGRA3 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99293418; called by muse, mutect2, varscan2
- ADGRG4 | c.5563C>T p.P1855S | Missense Mutation (SNP) | VAF 400/635 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777489023; called by muse, mutect2, varscan2
- ADGRG4 | c.6580C>T p.P2194S | Missense Mutation (SNP) | VAF 403/618 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV54967263; called by muse, mutect2, varscan2
- ADGRG4 | c.7502C>T p.S2501L | Missense Mutation (SNP) | VAF 117/535 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV54950755; called by muse, mutect2, varscan2
- ADGRL1 | c.3641C>T p.S1214L (on ENST00000340736 / NM_001008701.3; = p.S1209L on NM_014921.5) | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs746960334; called by muse, mutect2, varscan2
- ADGRL2 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 311/772 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54684247; called by muse, mutect2, varscan2
- ADGRV1 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 154/371 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs41305900; called by muse, mutect2, varscan2
- ADGRV1 | c.6779G>A p.R2260Q | Missense Mutation (SNP) | VAF 155/360 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs749204963, COSV101315594; called by muse, mutect2, varscan2
- AGRP | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs898112158; called by muse, mutect2, varscan2
- AIRE | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 267/546 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1030568996; called by muse, mutect2, varscan2
- AJAP1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 238/538 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs769421868, COSV65451311; called by muse, mutect2, varscan2
- AK8 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 188/416 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100050585; called by muse, mutect2, varscan2
- AKAP8L | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 189/433 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1401623346; called by muse, mutect2, varscan2
- AL645922.1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 864/1407 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs766612461; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 156/175 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- AMIGO2 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 161/441 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV56974882; called by muse, mutect2, varscan2
- AMOTL2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 285/618 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs368269741; called by muse, mutect2, varscan2
- ANK1 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 177/380 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs1486547831; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7501C>T p.P2501S | Missense Mutation (SNP) | VAF 223/505 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs145182659; called by muse, mutect2, varscan2
- ANKRD12 | c.5194C>A p.P1732T | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD12 | c.5195C>T p.P1732L | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs756983904; called by muse, mutect2, varscan2
- ANKRD18A | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 232/523 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV68804774; called by muse, mutect2, varscan2
- ANKRD30A | c.391G>A p.D131N (on ENST00000611781; = p.D75N on NM_052997.2) | Missense Mutation (SNP) | VAF 151/176 reads (86%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1231002205, COSV64609015; called by muse, mutect2, varscan2
- ANKRD30A | c.2858G>A p.G953E (on ENST00000611781; = p.G897E on NM_052997.2) | Missense Mutation (SNP) | VAF 65/72 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs538383318, COSV64606658; called by muse, mutect2, varscan2
- ANKRD36C | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54757281; called by muse, mutect2, varscan2
- ANKRD44 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 275/425 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99985541; called by muse, mutect2, varscan2
- ANO4 | c.950G>A p.R317Q (on ENST00000392977 / NM_001286615.2; = p.R282Q on NM_178826.4) | Missense Mutation (SNP) | VAF 172/340 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1202630749, COSV54594794; called by muse, varscan2
- ANO7 | c.1873G>A p.G625R (on ENST00000274979; = p.G571R on NM_001370694.2) | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1310969414; called by muse, mutect2, varscan2
- AOX1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 252/435 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65982781; called by muse, mutect2, varscan2
- APBA3 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 304/529 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1360096932; called by muse, mutect2, varscan2
- APC2 | c.6632C>T p.T2211I | Missense Mutation (SNP) | VAF 301/937 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs895565947; called by muse, mutect2, varscan2
- APCDD1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 323/666 reads (48%) | catalogued as rs373747410; called by muse, mutect2, varscan2
- APOB | c.9478G>A p.E3160K | Missense Mutation (SNP) | VAF 183/312 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs999346511, COSV51931380; called by muse, mutect2, varscan2
- APOB | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047759477; called by muse, mutect2, varscan2
- AQP7 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 310/669 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770503247; called by muse, mutect2, varscan2
- ARAP2 | c.4859A>G p.D1620G | Missense Mutation (SNP) | VAF 262/685 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV58288092, COSV58289219; called by muse, mutect2
- ARHGAP21 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 97/136 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995838696, COSV100255684; called by muse, mutect2, varscan2
- ARHGEF1 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 192/456 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1348787604; called by muse, mutect2, varscan2
- ARHGEF12 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs1188291844; called by muse, mutect2, varscan2
- ARHGEF16 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 324/766 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1047293018; called by muse, varscan2
- ARID3B | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 283/496 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1352982253; called by muse, mutect2, varscan2
- ARIH2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 214/428 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62704889; called by muse, varscan2
- ARMC12 | c.1009A>G p.K337E (on ENST00000373866 / NM_001286574.2; = p.K364E on NM_145028.5) | Missense Mutation (SNP) | VAF 154/475 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as rs950153284; called by muse, mutect2, varscan2
- ASPSCR1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 698/747 reads (93%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1413238488; called by muse, mutect2, varscan2
- ASS1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 192/474 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs773150312; called by muse, mutect2, varscan2
- ASTN2 | c.1196G>A p.G399E (on ENST00000313400 / NM_001365069.1; = p.G348E on NM_014010.5) | Missense Mutation (SNP) | VAF 159/340 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57796659; called by muse, mutect2, varscan2
- ASXL3 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs1440478761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11A | c.1026C>T p.F342= | Splice Region (SNP) | VAF 149/297 reads (50%) | catalogued as rs1387394606, COSV52124509; called by muse, mutect2, varscan2
- ATP13A4 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55070853; called by muse, mutect2, varscan2
- ATP13A4 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55068960; called by muse, mutect2, varscan2
- ATP1A3 | c.1201C>T p.H401Y (on ENST00000545399 / NM_001256214.2; = p.H388Y on NM_152296.5) | Missense Mutation (SNP) | VAF 173/363 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100131737; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 122/505 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- ATP8B2 | c.2885C>T p.P962L (on ENST00000672630; = p.P929L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 240/507 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV59245782; called by muse, mutect2, varscan2
- ATPSCKMT | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs762541865; called by muse, mutect2, varscan2
- ATRX | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 74/483 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64874398; called by muse, mutect2, varscan2
- BBS4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 204/364 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1251827333; called by muse, mutect2, varscan2
- BCAT1 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 207/245 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1334431288; called by muse, mutect2, varscan2
- BCL11B | c.1789A>G p.K597E (on ENST00000357195 / NM_001282237.2; = p.K526E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 303/782 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377444580; called by muse, mutect2, varscan2
- BCL11B | c.899G>C p.R300P (on ENST00000357195 / NM_001282237.2; = p.R229P on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 586/1132 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99068898; called by muse, mutect2, varscan2
- BEST3 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 169/471 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs753618473; called by muse, mutect2, varscan2
- BEX5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 210/674 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61328355; called by muse, mutect2, varscan2
- BMPER | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.29); catalogued as COSV51832005; called by muse, mutect2
- BRAP | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 216/387 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100554104; called by muse, mutect2, varscan2
- BRINP1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 240/498 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV56296860; called by muse, mutect2, varscan2
- BRINP1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 240/575 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV56303837, COSV56317776; called by muse, mutect2, varscan2
- BRINP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 272/657 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66513568; called by muse, varscan2
- BRS3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 154/604 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146164598, COSV101036705, COSV65710950; called by muse, varscan2
- C11orf80 | c.892-7A>G | Splice Region (SNP) | VAF 193/353 reads (55%) | catalogued as rs769257397; called by muse, mutect2, varscan2
- C11orf95 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 419/705 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV58311394; called by muse, mutect2, varscan2
- C12orf50 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 130/387 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as rs781126111; called by muse, mutect2, varscan2
- C12orf54 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 160/285 reads (56%) | catalogued as rs760341392, COSV58360190; called by muse, mutect2, varscan2
- C16orf46 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 79/409 reads (19%) | catalogued as rs145595395; called by muse, mutect2, varscan2
- C16orf78 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54555053; called by muse, mutect2, varscan2
- C19orf47 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 192/445 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs151320497; called by muse, mutect2, varscan2
- C19orf81 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 222/497 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs959581840; called by muse, mutect2, varscan2
- C1orf131 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 270/638 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs779405167, COSV59642948; called by muse, mutect2, varscan2
- C1orf68 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 429/798 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as rs1000090998, COSV64224530; called by muse, mutect2, varscan2
- C22orf39 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771216730; called by muse, mutect2, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 147/360 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, mutect2, varscan2
- C6orf132 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 628/1045 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as rs1233210366, COSV59375472; called by muse, mutect2, varscan2
- C9 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 122/219 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54680663; called by muse, mutect2, varscan2
- CABP1 | c.802G>A p.E268K (on ENST00000316803 / NM_001033677.1; = p.E65K on NM_004276.5) | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328676871, COSV56458203; called by muse, mutect2, varscan2
- CACNA1B | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 512/1055 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1292482427, COSV53115294; called by muse, mutect2, varscan2
- CACNA1E | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 274/664 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs551308908; called by muse, mutect2, varscan2
- CACNG3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 157/254 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV50063920; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 186/435 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, mutect2, varscan2
- CADPS2 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57364024; called by muse, mutect2, varscan2
- CAPN10 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 261/441 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867854825, COSV54377409; called by muse, mutect2, varscan2
- CARD6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV99620391; called by muse, mutect2, varscan2
- CARD6 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 192/454 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV54565204; called by muse, mutect2, varscan2
- CARD9 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 213/456 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs757521707; called by muse, mutect2, varscan2
- CATSPER1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 342/570 reads (60%) | SIFT tolerated (0.67); PolyPhen benign (0.078); catalogued as COSV56411379; called by muse, mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CCDC136 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52798951; called by muse, mutect2, varscan2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCDC168 | c.18253A>G p.R6085G | Missense Mutation (SNP) | VAF 144/447 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV100487624; called by muse, mutect2
- CCDC27 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 340/661 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.092); catalogued as COSV53902807; called by muse, mutect2, varscan2
- CCDC39 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM131302; called by muse, mutect2, varscan2
- CCDC60 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 152/291 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs576781017, COSV59546324; called by muse, mutect2, varscan2
- CCDC73 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs868393270, COSV100067237, COSV58797856; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCDC88C | c.4792C>T p.R1598W | Missense Mutation (SNP) | VAF 270/479 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57797256; called by muse, mutect2, varscan2
- CCNB3 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 259/293 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782348453; called by muse, mutect2, varscan2
- CCSER1 | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 137/149 reads (92%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV61415369; called by muse, mutect2, varscan2
- CCT2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs747101634; called by muse, mutect2, varscan2
- CD163L1 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 295/322 reads (92%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58011409; called by muse, mutect2, varscan2
- CD163L1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 221/250 reads (88%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV58021540; called by muse, mutect2, varscan2
- CD19 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346128809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD34 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 331/702 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60413657; called by muse, mutect2, varscan2
- CD86 | c.265G>A p.D89N (on ENST00000330540 / NM_175862.5; = p.D83N on NM_006889.4) | Missense Mutation (SNP) | VAF 246/504 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as COSV100053945; called by muse, varscan2
- CDH20 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 345/727 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs138127688, COSV53015177; called by muse, mutect2, varscan2
- CDH6 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 218/492 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV54063505; called by muse, mutect2, varscan2
- CDK10 | c.254G>A p.R85Q (on ENST00000353379 / NM_052988.5; = p.R14Q on NM_052987.4) | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757712230, COSV57045975; called by muse, mutect2, varscan2
- CDK9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 179/401 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs751991570, COSV64723870; called by muse, mutect2, varscan2
- CDKL5 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 190/219 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs764423452; called by muse, mutect2, varscan2
- CELSR1 | c.8414C>T p.S2805F | Missense Mutation (SNP) | VAF 168/341 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs755549263, COSV53086670; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>A p.G1755S | Missense Mutation (SNP) | VAF 167/477 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs745985122, COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- CFAP43 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 226/268 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV63852778; called by muse, mutect2, varscan2
- CFAP54 | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.138); catalogued as rs773999946, COSV61574963; called by muse, mutect2, varscan2
- CFAP54 | c.6471G>A p.M2157I | Missense Mutation (SNP) | VAF 116/168 reads (69%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV61573023; called by muse, mutect2, varscan2
- CFAP74 | c.1349T>G p.L450* | Nonsense Mutation (SNP) | VAF 5782/6077 reads (95%) | catalogued as COSV54567702; called by muse, mutect2, varscan2
- CFAP91 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 248/506 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs747341452, COSV56340952; called by muse, mutect2, varscan2
- CFHR1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 194/398 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57626219; called by muse, mutect2, varscan2
- CFHR4 | c.1273G>A p.G425R (on ENST00000367416 / NM_001201551.2; = p.G179R on NM_006684.5) | Missense Mutation (SNP) | VAF 197/508 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV99259324; called by muse, varscan2
- CFHR5 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs753176414; called by muse, mutect2, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 147/376 reads (39%) | catalogued as CM941971, COSV50041069; called by muse, mutect2, varscan2
- CFTR | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs397508302, CD972127, CM066545, CM067741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD1 | c.4437G>A p.W1479* | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as rs1329235381, COSV99399883; called by muse, mutect2, varscan2
- CHD4 | c.3145C>T p.L1049F (on ENST00000357008 / NM_001363606.2; = p.L1062F on NM_001273.5) | Missense Mutation (SNP) | VAF 183/199 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100537149; called by muse, mutect2, varscan2
- CHD5 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 192/524 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52412005; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHRD | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 252/585 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52608219; called by muse, mutect2
- CHRDL2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.375); catalogued as rs536498622, COSV55225561; called by muse, mutect2, varscan2
- CHRM3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 216/553 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382696054, COSV55089720; called by muse, mutect2, varscan2
- CIART | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 212/445 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs139897151; called by muse, mutect2, varscan2
- CIC | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 390/850 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as rs767155091; called by muse, varscan2
- CLCN6 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 231/589 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs373167140; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, mutect2, varscan2
- CLUAP1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 249/394 reads (63%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs143126195; called by muse, mutect2, varscan2
- CMYA5 | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 225/494 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs200982295; called by muse, mutect2, varscan2
- CNGB3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs1184824947, COSV60688088; called by muse, mutect2, varscan2
- CNNM4 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 216/374 reads (58%) | catalogued as rs1021713187, CM090738, COSV65660159; called by muse, mutect2, varscan2
- CNTN5 | c.325A>C p.I109L | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54275975; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2, varscan2
- CNTNAP5 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373323066; called by muse, mutect2, varscan2
- COL11A1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 248/707 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62185672, COSV62193987; called by muse, mutect2, varscan2
- COL14A1 | c.5288C>T p.S1763L | Missense Mutation (SNP) | VAF 171/405 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV52865949; called by muse, mutect2, varscan2
- COL18A1 | c.2228C>T p.T743I (on ENST00000359759 / NM_130444.3; = p.T508I on NM_030582.4) | Missense Mutation (SNP) | VAF 119/586 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs1427568442, COSV62706007; called by muse, mutect2, varscan2
- COL19A1 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 196/218 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs760925220, COSV59570978; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 393/644 reads (61%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by muse, mutect2, varscan2
- COL21A1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 283/488 reads (58%) | catalogued as rs767901816; called by muse, mutect2, varscan2
- COL22A1 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 207/467 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57339199; called by muse, mutect2, varscan2
- COL3A1 | c.2104G>A p.G702S | Missense Mutation (SNP) | VAF 172/311 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1512423; called by muse, mutect2, varscan2
- COL4A4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 189/595 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762822768, COSV61633794; called by muse, mutect2, varscan2
- COL4A5 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 144/432 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1437156555, COSV60374220; called by muse, mutect2, varscan2
- COL5A3 | c.4010G>A p.G1337E | Missense Mutation (SNP) | VAF 256/488 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868047902, COSV53418128; called by muse, mutect2, varscan2
- COL6A5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV55201496; called by muse, mutect2, varscan2
- CPA3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56045717; called by muse, mutect2, varscan2
- CPA3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 166/432 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs867230201, COSV56045225; called by muse, mutect2, varscan2
- CPA4 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 185/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55985487; called by muse, mutect2, varscan2
- CPLX4 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 193/410 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs781137378; called by muse, mutect2, varscan2
- CPNE4 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 128/317 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs751105787; called by muse, mutect2, varscan2
- CPNE6 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 315/563 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53746466; called by muse, mutect2, varscan2
- CPZ | c.1699A>G p.I567V (on ENST00000360986 / NM_001014447.3; = p.I556V on NM_003652.3) | Missense Mutation (SNP) | VAF 251/561 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.039); catalogued as rs527836142; called by muse, mutect2, varscan2
- CR2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 254/596 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV65506420; called by muse, mutect2, varscan2
- CRYBG2 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 219/575 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs955274470; called by muse, mutect2, varscan2
- CSF1R | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1411349452; called by muse, mutect2, varscan2
- CSF2RA | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 289/629 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1181481612, COSV100817746; called by muse, mutect2, varscan2
- CSMD1 | c.7508G>A p.G2503E (on ENST00000520002; = p.G2502E on NM_033225.6) | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV59310410; called by muse, mutect2, varscan2
- CSMD1 | c.6491C>T p.P2164L (on ENST00000520002; = p.P2163L on NM_033225.6) | Missense Mutation (SNP) | VAF 211/466 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772713616; called by muse, mutect2, varscan2
- CSMD1 | c.5104G>A p.E1702K (on ENST00000520002; = p.E1701K on NM_033225.6) | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59355311; called by muse, varscan2
- CSMD1 | c.5103G>A p.G1701= (on ENST00000520002; = p.G1700= on NM_033225.6) | Splice Region (SNP) | VAF 78/220 reads (35%) | catalogued as rs909928261, COSV59308408; called by muse, varscan2
- CSMD1 | c.933G>A p.V311= | Splice Region (SNP) | VAF 188/440 reads (43%) | catalogued as rs376995728; called by muse, mutect2, varscan2
- CSMD3 | c.9148+1G>A p.X3050_splice (on ENST00000297405 / NM_001363185.1; = p.X2881_splice on NM_052900.3) | Splice Site (SNP) | VAF 138/295 reads (47%) | catalogued as rs200499629, COSV52105444; called by muse, mutect2, varscan2
- CSMD3 | c.1477G>A p.E493K (on ENST00000297405 / NM_001363185.1; = p.E389K on NM_052900.3) | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52318007; called by muse, mutect2, varscan2
- CTNNBL1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 179/416 reads (43%) | catalogued as COSV63746696; called by muse, mutect2, varscan2
- CYLC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 250/525 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66336737, COSV66337270; called by muse, mutect2, varscan2
- CYLC2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369079750; called by muse, mutect2, varscan2
- CYP2A7 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 211/512 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502356; called by muse, mutect2, varscan2
- CYP3A4 | c.1484C>T p.S495F (on ENST00000336411; = p.S464F on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs768323664; called by muse, mutect2, varscan2
- CYP3A43 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV55936966; called by muse, mutect2, varscan2
- CYP4A11 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 181/396 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV60224482; called by muse, mutect2, varscan2
- CYP4B1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 219/427 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1047656596, COSV54724199; called by muse, mutect2, varscan2
- CYP4X1 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64150816; called by muse, mutect2, varscan2
- CYP4Z1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100497855, COSV100497985; called by muse, varscan2
- CYTH4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 221/466 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs865913340, COSV50635280; called by muse, mutect2, varscan2
- DAB1 | c.1265C>T p.T422I (on ENST00000371231; = p.T389I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 396/714 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1557545640, COSV64692713; called by muse, mutect2, varscan2
- DCHS1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 136/524 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs780012886; called by muse, varscan2
- DCUN1D3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 211/349 reads (60%) | catalogued as COSV60953014; called by muse, mutect2, varscan2
- DENND2C | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 172/476 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs772944552, COSV67920142; called by muse, mutect2, varscan2
- DGKI | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 170/335 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365470441; called by muse, mutect2, varscan2
- DHX34 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 278/548 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1170484982; called by muse, mutect2, varscan2
- DIAPH3 | c.1706G>A p.G569E (on ENST00000400324 / NM_001042517.2; = p.G306E on NM_030932.3) | Missense Mutation (SNP) | VAF 245/446 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs776635573; called by muse, mutect2, varscan2
- DLG5 | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 340/377 reads (90%) | catalogued as COSV64948372; called by muse, mutect2, varscan2
- DMBT1 | c.1784-1G>A p.X595_splice | Splice Site (SNP) | VAF 270/306 reads (88%) | catalogued as COSV100352470; called by muse, mutect2, varscan2
- DNAH10 | c.388C>T p.P130S (on ENST00000409039; = p.P69S on NM_207437.3) | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV68993374; called by muse, mutect2, varscan2
- DNAH11 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs371235859, COSV100177434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH14 | c.6139G>A p.E2047K (on ENST00000445597; = p.E2700K on NM_001367479.1) | Missense Mutation (SNP) | VAF 347/667 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1156837640, COSV59894733; called by muse, mutect2, varscan2
- DNAH2 | c.7103C>T p.S2368L | Missense Mutation (SNP) | VAF 377/422 reads (89%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs148494854, COSV66720502; called by muse, mutect2, varscan2
- DNAH2 | c.10277G>A p.R3426Q | Missense Mutation (SNP) | VAF 385/418 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as rs201968584; called by muse, mutect2, varscan2
- DNAH3 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759835468, COSV54509344; called by muse, mutect2, varscan2
- DNAH3 | c.4547G>A p.G1516E | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1190131377; called by muse, mutect2, varscan2
- DNAH3 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 166/239 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs541368919, COSV54529378; called by muse, mutect2, varscan2
- DNAH5 | c.11074C>T p.L3692F | Missense Mutation (SNP) | VAF 188/391 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1382261599; called by muse, mutect2, varscan2
- DNAH5 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 162/366 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54256658; called by muse, mutect2, varscan2
- DNAH5 | c.5498G>A p.G1833E | Missense Mutation (SNP) | VAF 107/299 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867913207; called by muse, mutect2, varscan2
- DNAH6 | c.6182G>A p.R2061Q | Missense Mutation (SNP) | VAF 212/322 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs765469238, CM162785; called by muse, mutect2, varscan2
- DNAH6 | c.6392C>T p.S2131L | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs867327643; called by muse, mutect2, varscan2
- DNAH7 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 218/344 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56788901; called by muse, mutect2, varscan2
- DNAH7 | c.3832C>T p.H1278Y | Missense Mutation (SNP) | VAF 140/226 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV56771861; called by muse, mutect2, varscan2
- DNAH8 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330298296, COSV59428426; called by muse, mutect2, varscan2
- DNAH8 | c.12947C>T p.S4316L | Missense Mutation (SNP) | VAF 162/687 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765766734, COSV59443932; called by muse, mutect2, varscan2
- DNAH9 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 216/236 reads (92%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1443985595, COSV52335653; called by muse, mutect2, varscan2
- DNAJB13 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 180/293 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV60269539; called by muse, mutect2, varscan2
- DNALI1 | c.424A>C p.I142L (on ENST00000296218; = p.I120L on NM_003462.5) | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as rs1227767571; called by muse, mutect2, varscan2
- DNMT3B | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 195/491 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749197342, COSV52415308; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2
- DOCK4 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 59/275 reads (21%) | catalogued as rs374816878; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 288/798 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DRD2 | c.1137C>T p.L379= | Splice Region (SNP) | VAF 60/213 reads (28%) | catalogued as rs752872204, COSV60763426; called by muse, mutect2, varscan2
- DSC1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 246/502 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57145311; called by muse, mutect2, varscan2
- DSC1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 152/395 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs267605150, COSV99937667; called by muse, varscan2
- DSC3 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 240/524 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV64572936, COSV64575730; called by muse, mutect2, varscan2
- DSCAM | c.3658C>T p.R1220* | Nonsense Mutation (SNP) | VAF 178/429 reads (41%) | catalogued as rs867787586; called by muse, mutect2, varscan2
- DSCAM | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101261371, COSV68033183; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 287/655 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSG2 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 222/493 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99852704; called by muse, mutect2, varscan2
- DZIP1L | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 237/553 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV59519783; called by muse, mutect2, varscan2
- EBF1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 257/552 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs750855534; called by muse, mutect2, varscan2
- EBF2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs751281440, COSV68776087; called by muse, varscan2
- EDAR | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 160/511 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.257); catalogued as COSV51502478; called by muse, mutect2, varscan2
- EFEMP1 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs781708447; called by muse, mutect2, varscan2
- EFHB | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 189/428 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV55544595; called by muse, mutect2, varscan2
- EGR3 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 299/673 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100416289; called by muse, mutect2, varscan2
- EHMT1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 230/544 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs727503916; ClinVar: uncertain significance; called by muse, mutect2
- EHMT1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 230/546 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1389665235; called by muse, mutect2
- ELF4 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 250/882 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs954660673; called by muse, mutect2, varscan2
- EMB | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV57480294; called by muse, mutect2, varscan2
- ENAM | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 232/266 reads (87%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs868759180, COSV68535291; called by muse, mutect2, varscan2
- EPAS1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 155/521 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as COSV55391640; called by muse, mutect2, varscan2
- EPB41L1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 131/594 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754822027, COSV52435165; called by muse, mutect2, varscan2
- ERF | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 364/857 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1219051518; called by muse, mutect2, varscan2
- ESM1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260213119, COSV101195624; called by muse, mutect2, varscan2
- ESR2 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 215/571 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371856990; called by muse, mutect2, varscan2
- ESRRB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 482/871 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1477346091, COSV55062198; ClinVar: uncertain significance; called by muse, varscan2
- EVA1C | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 257/627 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55827554; called by muse, mutect2, varscan2
- EXOC4 | c.2914A>T p.T972S | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV54109506; called by muse, mutect2, varscan2
- EXPH5 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 162/503 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs533686338; called by muse, mutect2, varscan2
- FADS6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 119/633 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1247592363, COSV100044033; called by muse, mutect2, varscan2
- FAM135B | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 186/447 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs370460671, COSV52731262; called by muse, mutect2, varscan2
- FAM13C | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 148/164 reads (90%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV53252796, COSV99513849; called by muse, mutect2, varscan2
- FAM170A | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); catalogued as rs750816456; called by muse, mutect2, varscan2
- FAM193A | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 230/544 reads (42%) | catalogued as COSV61198524; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 130/326 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM227B | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 138/268 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs1370229064, COSV54815190; called by muse, mutect2, varscan2
- FAM3D | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs761002325, COSV62559043; called by muse, mutect2, varscan2
- FAM47A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 366/412 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs1435553467, COSV100650088, COSV60499376; called by muse, mutect2, varscan2
- FAM47C | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 365/412 reads (89%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.687); catalogued as rs375607348, COSV63728240; called by muse, mutect2, varscan2
- FAM83G | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 498/558 reads (89%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV100524817; called by muse, mutect2, varscan2
- FAM90A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 271/591 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562876348, COSV56710170; called by muse, mutect2, varscan2
- FASN | c.4913C>T p.S1638F | Missense Mutation (SNP) | VAF 488/531 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100148252; called by muse, mutect2, varscan2
- FAT4 | c.9619G>A p.E3207K | Missense Mutation (SNP) | VAF 225/260 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868613088, COSV58715034; called by muse, mutect2, varscan2
- FAT4 | c.10799G>A p.G3600E | Missense Mutation (SNP) | VAF 190/217 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58678321; called by muse, mutect2, varscan2
- FBLN5 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV50903550; called by muse, mutect2, varscan2
- FCHO1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 264/484 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs530821806, COSV53183133; called by muse, mutect2
- FGD2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 266/889 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs761063246, COSV99236708; called by muse, mutect2, varscan2
- FGFBP1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 244/494 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs754608281, COSV99468902; called by muse, mutect2, varscan2
- FGFR3 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 301/722 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs751042118; called by muse, mutect2, varscan2
- FLG | c.10607G>A p.G3536E | Missense Mutation (SNP) | VAF 388/672 reads (58%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.874); catalogued as rs1279541481, COSV64240112; called by muse, varscan2
- FLG | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 304/766 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs754426329; called by muse, varscan2
- FLG | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 286/614 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.167); catalogued as rs369474474, COSV64243153; called by muse, varscan2
- FLNA | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 152/644 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs201823071, CM1511657; called by muse, mutect2, varscan2
- FLNC | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 200/392 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs760911646, COSV57962877; called by muse, varscan2
- FLT1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 367/697 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56723292; called by muse, mutect2, varscan2
- FLVCR2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 353/662 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as rs778286255, COSV53163029, COSV99471131; called by muse, mutect2, varscan2
- FMN2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 568/1193 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs755620586, COSV60457466; called by muse, mutect2, varscan2
- FMN2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.324); catalogued as rs1479970087, COSV100145528; called by muse, mutect2, varscan2
- FMNL2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 147/259 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56490889; called by muse, mutect2, varscan2
- FMR1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 224/368 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503710, COSV99503872; called by muse, mutect2, varscan2
- FNDC3A | c.938C>T p.S313L (on ENST00000492622 / NM_001079673.2; = p.S257L on NM_014923.5) | Missense Mutation (SNP) | VAF 167/434 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101001325; called by muse, mutect2, varscan2
- FRAS1 | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 173/212 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756919344; called by muse, mutect2, varscan2
- FRMD4B | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 174/418 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68331564; called by muse, mutect2, varscan2
- FRMPD3 | c.4499C>T p.A1500V | Missense Mutation (SNP) | VAF 372/679 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV99346962; called by muse, varscan2
- FRYL | c.8237C>T p.S2746F | Missense Mutation (SNP) | VAF 222/557 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.961); catalogued as rs780732528, COSV99977143; called by muse, mutect2, varscan2
- FSIP2 | c.7940C>T p.P2647L | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1268739398; called by muse, mutect2, varscan2
- FSTL5 | c.348A>T p.R116S | Missense Mutation (SNP) | VAF 191/213 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV104401727; called by muse, mutect2, varscan2
- GABRA2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 150/401 reads (37%) | catalogued as rs748381199; called by muse, mutect2, varscan2
- GABRA5 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 272/477 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1365550701; called by muse, mutect2, varscan2
- GAL3ST4 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 269/585 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as rs540539176; called by muse, mutect2, varscan2
- GALNT10 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs370969922, COSV51726166; called by muse, mutect2, varscan2
- GALNT13 | c.858G>A p.R286= | Splice Region (SNP) | VAF 114/193 reads (59%) | catalogued as COSV101222170, COSV67233749; called by muse, mutect2, varscan2
- GALNT13 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 136/234 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV67211781; called by muse, mutect2, varscan2
- GALP | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 207/465 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867751771, COSV61999251; called by muse, mutect2, varscan2
- GBE1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101450149; called by muse, mutect2, varscan2
- GBP2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 144/252 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs781516751; called by muse, mutect2, varscan2
- GDPD2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 293/538 reads (54%) | catalogued as COSV65532682; called by muse, mutect2, varscan2
- GGA3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 377/795 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99821723; called by muse, mutect2, varscan2
- GGT5 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 274/584 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1218880099, COSV99571366; called by muse, mutect2, varscan2
- GGT5 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 334/745 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV54070076; called by muse, mutect2, varscan2
- GJA1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 143/292 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); catalogued as rs1265740574, COSV56997529; called by muse, mutect2, varscan2
- GLI2 | c.4486G>A p.D1496N (on ENST00000361492 / NM_001374353.1; = p.D1513N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 284/511 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs755563767, COSV58033899; called by muse, mutect2, varscan2
- GLYAT | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 193/338 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53538375; called by muse, mutect2, varscan2
- GOLGA4 | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 181/442 reads (41%) | catalogued as COSV62710265; called by muse, mutect2, varscan2
- GOLGA8S | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1190506399, COSV73788191; called by muse, mutect2, varscan2
- GPR32 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 283/656 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54514279; called by muse, mutect2, varscan2
- GPRC6A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 201/233 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369734914, COSV59953059; called by muse, mutect2, varscan2
- GRIN2A | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1245573153, COSV58022910; called by muse, mutect2, varscan2
- GRIN2A | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV58029542; called by muse, mutect2, varscan2
- GRIP1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99671277; called by muse, mutect2, varscan2
- GRM7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 207/493 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63158538; called by muse, varscan2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 233/498 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by muse, mutect2, varscan2
- GSDMC | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV52697840; called by muse, mutect2, varscan2
- GSTA2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 260/419 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV72415254; called by muse, mutect2, varscan2
- HARS2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.936); catalogued as rs1401967821; called by muse, mutect2, varscan2
- HAUS7 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 169/680 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs782807039, COSV57849402; called by muse, mutect2, varscan2
- HAUS7 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 169/677 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV57848660; called by muse, mutect2, varscan2
- HAVCR1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 198/418 reads (47%) | catalogued as COSV59397432, COSV59401595; called by muse, varscan2
- HCN3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 530/1112 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.339); catalogued as rs1413271531; called by muse, mutect2, varscan2
- HGD | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866380660; called by muse, mutect2, varscan2
- HHIPL2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 233/533 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV58566285; called by muse, mutect2, varscan2
- HIVEP1 | c.6821C>T p.P2274L | Missense Mutation (SNP) | VAF 439/714 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs770790070; called by muse, mutect2, varscan2
- HMCN2 | c.13231G>T p.V4411L | Missense Mutation (SNP) | VAF 318/721 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV70934715; called by muse, mutect2, varscan2
- HOXB5 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); catalogued as rs1276718933, COSV99494340; called by muse, mutect2, varscan2
- HS3ST1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 255/545 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1270148575; called by muse, mutect2, varscan2
- HS6ST2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 264/426 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs866391579, COSV63711877; called by muse, mutect2, varscan2
- HSF4 | c.1022C>T p.P341L (on ENST00000521374 / NM_001040667.3; = p.P311L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 261/395 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206776401; called by muse, mutect2, varscan2
- HTR2C | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 180/640 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1251816359, COSV52203430, COSV52215308; called by muse, varscan2
- HYDIN | c.13642C>T p.R4548C | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201203817, COSV101125081; called by muse, mutect2, varscan2
- HYDIN | c.10639G>A p.E3547K | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as COSV66858470; called by muse, mutect2, varscan2
- IGDCC4 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 178/582 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.054); catalogued as COSV100733200, COSV61535523; called by muse, mutect2, varscan2
- IGHG3 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 467/814 reads (57%) | catalogued as rs1566732422; called by muse, mutect2, varscan2
- IGHV3-23 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 197/619 reads (32%) | catalogued as rs1164728836; called by muse, mutect2, varscan2
- IGHV3-23 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 92/450 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.296); catalogued as rs782495642; called by mutect2, varscan2
- IGHV3-53 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 168/408 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as rs782504417; called by muse, varscan2
- IGKV3OR2-268 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs1396199636; called by muse, mutect2, varscan2
- IGLV11-55 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 165/415 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772200742; called by muse, mutect2, varscan2
- IGSF10 | c.5925G>A p.W1975* | Nonsense Mutation (SNP) | VAF 98/479 reads (20%) | catalogued as rs867337533; called by muse, mutect2, varscan2
- IGSF10 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 264/544 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1365109350; called by muse, mutect2, varscan2
- IHO1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 338/643 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs1179321798; called by muse, mutect2, varscan2
- IL27RA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 255/476 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV54600233; called by muse, mutect2, varscan2
- IL2RB | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 302/718 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV53425048; called by muse, mutect2, varscan2
- IL36A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 182/330 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs866220179, COSV52082919; called by muse, mutect2, varscan2
- IL36B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 109/385 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs755811144, COSV52084410; called by muse, mutect2, varscan2
- INHBC | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 276/502 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as rs1470332298; called by muse, mutect2, varscan2
- INTS6L | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 172/599 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1177830333; called by muse, mutect2, varscan2
- IQCA1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99609400; called by muse, mutect2, varscan2
- IQCH | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs780947039; called by muse, mutect2, varscan2
- IRGC | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 176/834 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764460673; called by muse, mutect2, varscan2
- ITGA1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 152/300 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140779034; called by muse, mutect2, varscan2
- ITGAX | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51646916; called by muse, mutect2, varscan2
- ITLN1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100406260; called by muse, varscan2
- ITM2A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64810927; called by muse, mutect2, varscan2
- IVL | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 233/524 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.581); catalogued as rs201971901; called by muse, mutect2, varscan2
- IVL | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 397/892 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.382); catalogued as rs541702541, COSV100908137; called by muse, varscan2
- IWS1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 152/492 reads (31%) | catalogued as COSV54870217; called by muse, mutect2, varscan2
- JAM2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 125/271 reads (46%) | catalogued as rs781476062; called by muse, mutect2, varscan2
- JCAD | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 281/314 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs763764027, COSV64760999; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148623870; called by muse, mutect2, varscan2
- KALRN | c.7375G>A p.E2459K (on ENST00000360013 / NM_001024660.4; = p.E762K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/394 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.992); catalogued as COSV52262789; called by muse, mutect2, varscan2
- KANK4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 413/718 reads (58%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201256809, COSV62985569; called by muse, mutect2, varscan2
- KCNB1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 316/696 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV65567159; called by muse, mutect2, varscan2
- KCNH7 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100148690, COSV59797530; called by muse, mutect2, varscan2
- KCNJ15 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 294/701 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.156); catalogued as rs1227840730, COSV60811113; called by muse, mutect2
- KCNJ4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 302/762 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57859103; called by muse, mutect2, varscan2
- KCTD19 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 229/360 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs1210488903; called by muse, mutect2, varscan2
- KDM5B | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 279/572 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs765004569, COSV52506637, COSV52510135; called by muse, mutect2, varscan2
- KIAA0408 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 258/286 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772770879; called by muse, mutect2, varscan2
- KIAA1522 | c.1504G>A p.G502S (on ENST00000373480 / NM_001198972.2; = p.G561S on NM_020888.3) | Missense Mutation (SNP) | VAF 492/988 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759839842; called by muse, mutect2, varscan2
- KIAA1614 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 439/879 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs575391757, COSV62551133; called by muse, mutect2, varscan2
- KIF20B | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 104/130 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767771862; called by muse, mutect2, varscan2
- KIRREL3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 128/419 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs755625697; called by muse, mutect2, varscan2
- KLK13 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 237/575 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1209982241; called by muse, mutect2, varscan2
- KMT2D | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 280/532 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs199724002, COSV56409523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA5 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 181/201 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as rs147305551, COSV62652787; called by muse, mutect2, varscan2
- KRT10 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 587/619 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV54088142, COSV54088254; called by muse, mutect2, varscan2
- KRT26 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 191/492 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868550000; called by muse, mutect2, varscan2
- KRT33A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 359/386 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs751294091; called by muse, mutect2, varscan2
- KRT6C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 168/492 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as rs542254329; called by muse, varscan2
- KRTAP2-1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 300/933 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs1238572660, COSV101195354; called by muse, mutect2, varscan2
- KSR2 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 264/509 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195027; called by muse, mutect2, varscan2
- KSR2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 176/529 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV60368131; called by muse, mutect2, varscan2
- L1TD1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63133709; called by muse, mutect2, varscan2
- LACRT | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 144/275 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1455770578; called by muse, mutect2, varscan2
- LAMA1 | c.7078C>T p.R2360C | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs765870262, COSV67534647; called by muse, mutect2, varscan2
- LAMA5 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 95/479 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.076); catalogued as rs748077073; called by muse, mutect2, varscan2
- LANCL2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376130597; called by muse, mutect2, varscan2
- LCN9 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 159/385 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs373991789, COSV99479501; called by muse, mutect2, varscan2
- LEPR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 186/544 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598694, COSV62747060; called by muse, mutect2, varscan2
- LGSN | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 190/214 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1040530696; called by muse, mutect2, varscan2
- LHCGR | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 138/455 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs149917479, COSV54297069; called by muse, mutect2, varscan2
- LILRB2 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 399/909 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV58747468; called by muse, mutect2, varscan2
- LIN54 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 194/203 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100464552; called by muse, mutect2, varscan2
- LIN7A | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 187/328 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV54024589; called by muse, varscan2
- LINGO2 | c.308A>C p.N103T | Missense Mutation (SNP) | VAF 265/532 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs376791650; called by muse, mutect2, varscan2
- LRP1B | c.10082G>A p.R3361Q | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV67196916, COSV67285422; called by muse, varscan2
- LRRC40 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 168/488 reads (34%) | catalogued as rs1042273638; called by muse, mutect2, varscan2
- LRRC55 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 202/577 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs374511641, COSV73006823; called by muse, mutect2, varscan2
- LRRC7 | c.877C>T p.L293F (on ENST00000651989 / NM_001370785.2; = p.L260F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 280/492 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50466301; called by muse, mutect2, varscan2
- LUM | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 243/441 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57127897; called by muse, mutect2, varscan2
- LYPD4 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 131/595 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs782199915, COSV58028284; called by muse, mutect2, varscan2
- MAGEA11 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 353/581 reads (61%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.631); catalogued as rs1557362407; called by muse, mutect2, varscan2
- MAGEC1 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 460/716 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs748918214; called by muse, varscan2
- MAGEC1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 475/814 reads (58%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.968); catalogued as COSV53579808; called by muse, mutect2, varscan2
- MAGEC1 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 438/696 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs867630448; called by muse, mutect2, varscan2
- MAGEE1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 94/694 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV63910436; called by muse, varscan2
- MAGI2 | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1563153542, COSV62684224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MALRD1 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 257/284 reads (90%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1338072414; called by muse, mutect2, varscan2
- MAP1A | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 269/434 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55808448; called by muse, mutect2, varscan2
- MAP3K14 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 495/527 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767382383; called by muse, mutect2, varscan2
- MAP4K5 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 105/183 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1255887449; called by muse, mutect2, varscan2
- MARCHF2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 167/316 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.435); catalogued as rs375503291; called by muse, mutect2, varscan2
- MEGF6 | c.2893G>A p.G965R | Missense Mutation (SNP) | VAF 370/732 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs779065913; called by muse, varscan2
- METTL11B | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 168/404 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV63030129; called by muse, mutect2, varscan2
- MFRP | c.422G>A p.R141Q (on ENST00000449574; = p.R517Q on NM_031433.4) | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs767870051; called by muse, mutect2, varscan2
- MISP | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 196/600 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV53121970; called by muse, mutect2, varscan2
- MLKL | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV58206086; called by muse, mutect2, varscan2
- MMP15 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.607); catalogued as rs141624298; called by muse, mutect2, varscan2
- MMP8 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 52/182 reads (29%) | catalogued as rs1273485096; called by muse, mutect2, varscan2
- MMRN2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 201/224 reads (90%) | SIFT tolerated (0.3); PolyPhen benign (0.289); catalogued as rs762579403; called by muse, mutect2, varscan2
- MMUT | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 436/729 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs769922244, CM060368, CM060370, COSV51286554; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1767A>G p.I589M | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.322); catalogued as rs747877316; called by muse, mutect2, varscan2
- MROH2B | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 149/380 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV101270807; called by muse, mutect2, varscan2
- MROH2B | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.115); catalogued as rs868730638, COSV68189234; called by muse, mutect2, varscan2
- MS4A8 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100282522; called by muse, mutect2, varscan2
- MSH3 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 209/442 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs199659527, COSV54146901; ClinVar: uncertain significance; called by muse, varscan2
- MSR1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50523234; called by muse, mutect2, varscan2
- MTNR1B | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57065305; called by muse, mutect2, varscan2
- MTRES1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 184/210 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100261239; called by muse, mutect2, varscan2
- MUC12 | c.10342C>T p.P3448S (on ENST00000379442; = p.P3305S on NM_001164462.1) | Missense Mutation (SNP) | VAF 339/5308 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1374203028; called by muse, mutect2
- MUC16 | c.29965C>T p.P9989S | Missense Mutation (SNP) | VAF 182/304 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs866730767; called by muse, varscan2
- MUC16 | c.28658C>T p.S9553F | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs751932910; called by muse, mutect2, varscan2
- MUC16 | c.11938C>T p.P3980S | Missense Mutation (SNP) | VAF 238/414 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs761414131; called by muse, mutect2, varscan2
- MUC16 | c.11140C>T p.H3714Y | Missense Mutation (SNP) | VAF 169/301 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs867039375, COSV67487590; called by muse, mutect2, varscan2
- MUC16 | c.9587C>T p.S3196F | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs750830815; called by muse, mutect2, varscan2
- MUC16 | c.9545C>T p.P3182L | Missense Mutation (SNP) | VAF 124/395 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.254); catalogued as COSV101198527, COSV67465828; called by muse, mutect2, varscan2
- MUC3A | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 287/635 reads (45%) | SIFT deleterious, low confidence (0.01); catalogued as rs759978968; called by muse, mutect2, varscan2
- MUC4 | c.6832C>T p.L2278F | Missense Mutation (SNP) | VAF 109/960 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.598); catalogued as rs771281731; called by muse, mutect2
- MUC5AC | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 207/626 reads (33%) | SIFT deleterious (0); catalogued as rs902560168; called by muse, mutect2, varscan2
- MYH1 | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 239/415 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs1407451831; called by muse, mutect2, varscan2
- MYH15 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 213/478 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56316451; called by muse, mutect2, varscan2
- MYH4 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 257/275 reads (93%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as rs371573424; called by muse, mutect2, varscan2
- MYH8 | c.5480G>A p.G1827E | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV67963082, COSV67963478; called by muse, mutect2, varscan2
- MYLK | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 216/500 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60605014; called by muse, mutect2, varscan2
- MYO16 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs868261824, COSV51781539; called by muse, mutect2, varscan2
- MYO3A | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 192/231 reads (83%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.15); catalogued as COSV56334984, COSV56352401; called by muse, mutect2, varscan2
- MYO5B | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs993447719; called by muse, mutect2, varscan2
- MYOM2 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 182/364 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50745884, COSV50796799; called by muse, mutect2, varscan2
- MYOM2 | c.3049C>A p.P1017T | Missense Mutation (SNP) | VAF 142/305 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50763818; called by muse, mutect2, varscan2
- NADSYN1 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100034346; called by muse, mutect2, varscan2
- NADSYN1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100035022; called by muse, mutect2, varscan2
- NALCN | c.4139C>T p.T1380I | Missense Mutation (SNP) | VAF 240/475 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51944342; called by muse, mutect2, varscan2
- NARS2 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 176/284 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481123553, COSV55249884; called by muse, mutect2, varscan2
- NASP | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 110/373 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs896757778, COSV63111970; called by muse, mutect2
- NAV2 | c.4192C>T p.H1398Y (on ENST00000396087 / NM_001244963.2; = p.H1375Y on NM_145117.5) | Missense Mutation (SNP) | VAF 281/555 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1194398058; called by muse, mutect2, varscan2
- NCKAP1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1184998419, COSV62943970; called by muse, mutect2, varscan2
- NEB | c.15776G>A p.W5259* | Nonsense Mutation (SNP) | VAF 100/358 reads (28%) | catalogued as COSV50806836; called by muse, varscan2
- NELL2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 174/322 reads (54%) | catalogued as COSV61576934; called by muse, mutect2, varscan2
- NEXMIF | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 259/693 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV50080191; called by muse, mutect2, varscan2
- NF1 | c.3975-1G>A p.X1325_splice | Splice Site (SNP) | VAF 209/234 reads (89%) | catalogued as CS153440, COSV100647043, COSV62200559; called by muse, mutect2, varscan2
- NF1 | c.3975G>A p.R1325= | Splice Region (SNP) | VAF 194/218 reads (89%) | catalogued as COSV62192944; called by muse, varscan2
- NFAM1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 261/587 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs150375095; called by muse, mutect2, varscan2
- NFE2L1 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 610/650 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1428181976; called by muse, mutect2, varscan2
- NGLY1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 271/567 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99770413; called by muse, mutect2, varscan2
- NIFK | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs761077196, COSV53534615; called by muse, mutect2, varscan2
- NINL | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 184/430 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs759264606; called by muse, mutect2
- NLRP3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 411/780 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1475824860, COSV100276559, COSV60220608; called by muse, mutect2, varscan2
- NLRP4 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 136/342 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV56723100; called by muse, mutect2, varscan2
- NOBOX | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769328958, COSV56192923; called by muse, mutect2, varscan2
- NOTCH4 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 235/776 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1041838804; called by muse, mutect2, varscan2
- NOX1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 207/354 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs865995944, COSV99471785; called by muse, mutect2, varscan2
- NRG3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 177/216 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV64562880; called by muse, mutect2, varscan2
- NRK | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 373/659 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs372847875, COSV99686720; called by muse, mutect2, varscan2
- NRXN3 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 215/620 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs1203264894; called by muse, mutect2, varscan2
- NSD1 | c.7595C>T p.S2532L | Missense Mutation (SNP) | VAF 248/555 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV61779603; called by muse, mutect2, varscan2
- NT5C1B | c.934C>T p.L312F (on ENST00000359846 / NM_001199086.2; = p.L252F on NM_033253.4) | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV58399655; called by muse, mutect2, varscan2
- NUGGC | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs374292249; called by muse, mutect2, varscan2
- NUTM2F | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 143/390 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs1323216273; called by muse, mutect2, varscan2
- NXPH2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 121/466 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55645923; called by muse, mutect2, varscan2
- NYAP1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 252/538 reads (47%) | catalogued as COSV55723198; called by muse, varscan2
- NYAP1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 250/554 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs143758472, COSV55720544; called by muse, varscan2
- OBP2A | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs775504301, COSV59790985; called by muse, mutect2
- OCSTAMP | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 285/641 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV54098816; called by muse, mutect2, varscan2
- OOSP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 132/234 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140171460, COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- OPTC | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 352/721 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100921850; called by muse, mutect2, varscan2
- OR10A5 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 158/281 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750209370, COSV55053347; called by muse, mutect2, varscan2
- OR10H5 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 359/654 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.337); catalogued as rs575365825, COSV58277696; called by muse, mutect2, varscan2
- OR10Q1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 272/478 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV57471788; called by muse, mutect2, varscan2
- OR13C8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 153/331 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs867329527, COSV58611239; called by muse, mutect2, varscan2
- OR14A16 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 261/546 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs866940782, COSV62926444; called by muse, mutect2, varscan2
- OR1F1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs953195042; called by muse, mutect2, varscan2
- OR1Q1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 209/492 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs144709927, COSV52918475; called by muse, mutect2, varscan2
- OR2AE1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 230/504 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs905385422; called by muse, mutect2, varscan2
- OR2G2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 285/644 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740372; called by muse, mutect2, varscan2
- OR2G6 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 323/766 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100598017; called by muse, mutect2, varscan2
- OR2J1 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749161186; called by muse, mutect2, varscan2
- OR2M5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 297/698 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs139017053; called by muse, mutect2, varscan2
- OR2T3 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 219/495 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs1425555169; called by muse, mutect2, varscan2
- OR2T33 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 310/1039 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58818332; called by muse, mutect2, varscan2
- OR2T33 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 455/1062 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100532328, COSV58816478; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 227/646 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR51B5 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 143/245 reads (58%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56175038; called by muse, mutect2, varscan2
- OR51F1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 184/370 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs369623823; called by muse, mutect2
- OR51G1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1284781185; called by muse, mutect2, varscan2
- OR52E4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 229/377 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs144620167; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 214/344 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 247/409 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR52N1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1403316614, COSV57692994; called by muse, mutect2, varscan2
- OR5H1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 210/500 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs200751012; called by muse, mutect2, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 203/432 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, mutect2, varscan2
- OR5L2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 297/491 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445768587; called by muse, mutect2, varscan2
- OR5M1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV73202117; called by muse, mutect2, varscan2
- OR6C65 | c.874A>G p.N292D | Missense Mutation (SNP) | VAF 152/288 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101110203; called by muse, mutect2, varscan2
- OR8B2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 114/380 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66664714; called by muse, mutect2
- OR8D1 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63442247; called by muse, mutect2, varscan2
- OR8J3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV56880208, COSV56883621; called by muse, mutect2, varscan2
- OR8K3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 251/422 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs767024951; called by muse, mutect2, varscan2
- OR9Q1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV59044366; called by muse, mutect2, varscan2
- ORAI2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 305/627 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1198195830; called by muse, mutect2, varscan2
- OTOG | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as rs774229562; called by muse, mutect2, varscan2
- OTOG | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61129789; called by muse, mutect2, varscan2
- OTOG | c.7567C>T p.H2523Y | Missense Mutation (SNP) | VAF 124/435 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1314439748; called by muse, mutect2, varscan2
- OTOGL | c.6041C>T p.P2014L (on ENST00000547103; = p.P2005L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/351 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV54023488; called by muse, mutect2, varscan2
- PAM | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371136481; called by muse, mutect2, varscan2
- PAPPA | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs142893148, COSV60294044; called by muse, mutect2, varscan2
- PAPPA2 | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 237/586 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62790680; called by muse, mutect2, varscan2
- PAQR4 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 158/661 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs566373345, COSV99234321; called by muse, mutect2, varscan2
- PATJ | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 266/761 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1278118763; called by muse, mutect2, varscan2
- PAX8 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 254/420 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54511538; called by muse, mutect2, varscan2
- PCDHA1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 233/496 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65375119; called by muse, mutect2, varscan2
- PCDHA2 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 373/838 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65368946; called by muse, mutect2, varscan2
- PCDHA3 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV65364477; called by mutect2, varscan2
- PCDHA5 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 433/978 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV65353988; called by muse, mutect2, varscan2
- PCDHA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 160/174 reads (92%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65334627; called by muse, mutect2, varscan2
- PCDHB15 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 293/930 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1307688694; called by muse, mutect2, varscan2
- PCDHB5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 174/413 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV50647190; called by muse, mutect2, varscan2
- PCDHB5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 219/448 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554275831, COSV50649076; called by muse, mutect2, varscan2
- PCDHGA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as rs1046340065, COSV53927958; called by muse, mutect2, varscan2
- PCLO | c.12611C>T p.S4204L | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61617546; called by muse, mutect2, varscan2
- PCLO | c.12391G>A p.E4131K | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61640605; called by muse, mutect2, varscan2
- PCLO | c.10219G>A p.E3407K | Missense Mutation (SNP) | VAF 206/474 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1282303356, COSV61621336; called by muse, mutect2, varscan2
- PCLO | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 234/484 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs200555866; called by muse, mutect2, varscan2
- PCLO | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 212/441 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61652677; called by muse, mutect2, varscan2
- PDE1A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 123/215 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs747334904, COSV59513247; called by muse, mutect2, varscan2
- PDGFRA | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 144/159 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57265331; called by muse, mutect2, varscan2
- PDHA2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 311/346 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV54781493; called by muse, mutect2, varscan2
- PDS5A | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 125/247 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs767207351; called by muse, mutect2, varscan2
- PDZD7 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 349/394 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148695069, CM1513240, COSV64646209; called by muse, mutect2, varscan2
- PERCC1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 324/498 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs533187594; called by muse, varscan2
- PGAP6 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 80/399 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs748656747, COSV51739334, COSV51741491; called by muse, mutect2, varscan2
- PHLPP1 | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 245/578 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs759804178; called by muse, mutect2, varscan2
- PHRF1 | c.4622C>T p.S1541L (on ENST00000264555 / NM_001286581.2; = p.S1540L on NM_020901.4) | Missense Mutation (SNP) | VAF 233/765 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs368798093; called by muse, mutect2, varscan2
- PIEZO2 | c.7069G>A p.D2357N | Missense Mutation (SNP) | VAF 245/493 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1474217845, COSV99554996; called by muse, mutect2, varscan2
- PIK3R4 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV63244219; called by muse, mutect2, varscan2
- PKD1L3 | c.5036G>A p.G1679E | Missense Mutation (SNP) | VAF 131/223 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100324677; called by muse, mutect2, varscan2
- PLA2G4E | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868610633; called by muse, mutect2, varscan2
- PLB1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 100/399 reads (25%) | catalogued as rs369610326; called by muse, mutect2, varscan2
- PLCB2 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 160/599 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs750702293, COSV53031961; called by muse, mutect2, varscan2
- PLCB4 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753931051, COSV53798516; called by muse, mutect2, varscan2
- PLCE1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 265/303 reads (87%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs754397478, COSV53376651; called by muse, mutect2, varscan2
- PLCH1 | c.2830G>A p.D944N (on ENST00000340059 / NM_001130960.2; = p.D936N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 247/564 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV58189158; called by muse, mutect2, varscan2
- PLCH2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 222/7597 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs771815726; called by muse, mutect2
- PLCZ1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 148/168 reads (88%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV99855703; called by muse, mutect2, varscan2
- PLD1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs745380460; called by muse, mutect2, varscan2
- PLD5 | c.1064C>T p.T355I (on ENST00000442594; = p.T293I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/416 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV100138889; called by muse, mutect2, varscan2
- PLEKHA7 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60580513; called by muse, mutect2, varscan2
- PLEKHG6 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 372/410 reads (91%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV50600093; called by muse, mutect2, varscan2
- PMFBP1 | c.1783C>T p.R595C (on ENST00000537465; = p.R590C on NM_031293.3) | Missense Mutation (SNP) | VAF 139/219 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs149578677, COSV99401367; called by muse, mutect2, varscan2
- PODN | c.274G>A p.E92K (on ENST00000395871; = p.E44K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 466/1037 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs769165495, COSV57010995; called by muse, mutect2, varscan2
- POF1B | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 273/492 reads (55%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53137868; called by muse, mutect2, varscan2
- POLE | c.6058C>T p.P2020S | Missense Mutation (SNP) | VAF 352/644 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV57692027; called by muse, mutect2, varscan2
- POLE | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 324/561 reads (58%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); catalogued as COSV57693443; called by muse, mutect2, varscan2
- POLI | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54191689; called by muse, mutect2, varscan2
- POLI | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371876172; called by muse, mutect2, varscan2
- POLR1A | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 240/391 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55691483; called by muse, mutect2, varscan2
- POLRMT | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV73933405; called by muse, mutect2, varscan2
- POM121L12 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 334/748 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs750523098, COSV101375017; called by muse, mutect2, varscan2
- POTEF | c.2229G>A p.M743I | Missense Mutation (SNP) | VAF 90/889 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV62543084; called by muse, mutect2
- POTEG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 96/546 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs758824790; called by muse, varscan2
- POTEG | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 344/1970 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs753239019, COSV101611941; called by muse, varscan2
- POU3F1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 406/702 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1291000847; called by muse, varscan2
- POU6F2 | c.885G>A p.Q295= | Splice Region (SNP) | VAF 173/390 reads (44%) | catalogued as COSV68878060; called by muse, mutect2, varscan2
- PPFIA2 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs550703985; called by muse, varscan2
- PPP1R2C | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 172/200 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs1173919536, COSV65364021; called by muse, mutect2, varscan2
- PPP2R3A | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 205/469 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.201); catalogued as COSV53872344; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 223/553 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 190/472 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, varscan2
- PRG4 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 460/989 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771143941, COSV63354989; called by mutect2, varscan2
- PRH1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 178/503 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101457518; called by muse, varscan2
- PRKAA2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 278/524 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409708472, COSV100982756; called by muse, mutect2, varscan2
- PRKACG | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 221/501 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55240892; called by muse, mutect2, varscan2
- PRKD2 | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 320/679 reads (47%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.953); catalogued as rs779171577; called by muse, mutect2, varscan2
- PRND | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 272/661 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); catalogued as rs571957668, COSV99045316; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRT4 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 292/647 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as rs752145973; called by muse, mutect2, varscan2
- PRUNE2 | c.7493G>A p.G2498E | Missense Mutation (SNP) | VAF 157/304 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65043002; called by muse, mutect2, varscan2
- PRUNE2 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 235/526 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65042174; called by muse, mutect2, varscan2
- PTCHD4 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 208/551 reads (38%) | catalogued as rs753250425; called by muse, mutect2, varscan2
- PTEN | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 188/252 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64289137; called by muse, mutect2, varscan2
- PTF1A | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1038493023; called by muse, mutect2, varscan2
- PTPRB | c.5756G>A p.R1919Q | Missense Mutation (SNP) | VAF 155/388 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200824991; called by muse, mutect2, varscan2
- PTPRB | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs750869262, COSV54239121; called by muse, mutect2, varscan2
- PTPRD | c.3876G>A p.R1292= | Splice Region (SNP) | VAF 141/293 reads (48%) | catalogued as rs1015998828; called by muse, mutect2, varscan2
- PTPRN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 266/694 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67039045; called by muse, mutect2
- PTPRR | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 160/430 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV51731015; called by muse, mutect2, varscan2
- PTPRR | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144153905; called by muse, mutect2, varscan2
- PTPRT | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 269/681 reads (40%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.995); catalogued as COSV61987668, COSV62010614; called by muse, mutect2, varscan2
- PTX4 | c.1174G>A p.G392S (on ENST00000447419 / NM_001328608.2; = p.G387S on NM_001013658.1) | Missense Mutation (SNP) | VAF 109/479 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs758849133; called by muse, mutect2, varscan2
- PXDNL | c.2990T>C p.V997A | Missense Mutation (SNP) | VAF 262/553 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs536430275, COSV62501827; called by muse, mutect2, varscan2
- PZP | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 177/194 reads (91%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as rs771108767; called by muse, mutect2, varscan2
- QSER1 | c.1999C>T p.P667S (on ENST00000399302; = p.P796S on NM_001076786.3) | Missense Mutation (SNP) | VAF 150/227 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768155722; called by muse, mutect2, varscan2
- RALGAPA2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1287668959; called by muse, mutect2, varscan2
- RBM25 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 217/392 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1294642356, COSV56199734; called by muse, mutect2, varscan2
- RBP4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 286/329 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs766365350, COSV65159613; called by muse, mutect2, varscan2
- RCE1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 224/406 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs775687215; called by muse, mutect2, varscan2
- RCSD1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 213/526 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750952554, COSV63257970; called by muse, mutect2, varscan2
- RECQL4 | c.2463+1G>T p.X821_splice | Splice Site (SNP) | VAF 82/418 reads (20%) | catalogued as COSV99467365; called by mutect2, varscan2
- RGS6 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 170/469 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667013; called by muse, mutect2, varscan2
- RGS7BP | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.806); catalogued as rs151111266; called by muse, mutect2, varscan2
- RHOT2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 229/367 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1175144692; called by muse, mutect2, varscan2
- RIMS2 | c.2425C>T p.R809W (on ENST00000666250 / NM_001348490.2; = p.R617W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 179/447 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556481632, COSV99180199; called by muse, mutect2, varscan2
- RIMS2 | c.4110A>T p.E1370D (on ENST00000666250 / NM_001348490.2; = p.E941D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 202/459 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51669480; called by muse, mutect2, varscan2
- RIPOR3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 329/825 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.271); catalogued as rs969301387; called by muse, varscan2
- RNASE2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 357/632 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58941672; called by muse, mutect2, varscan2
- RNF128 | c.797G>A p.G266E (on ENST00000255499 / NM_194463.2; = p.G240E on NM_024539.3) | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55253331; called by muse, mutect2, varscan2
- RNF128 | c.916C>T p.P306S (on ENST00000255499 / NM_194463.2; = p.P280S on NM_024539.3) | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771248841; called by muse, mutect2, varscan2
- ROBO2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as rs372913645; called by muse, mutect2, varscan2
- ROBO2 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 306/661 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.073); catalogued as COSV59936464; called by muse, mutect2, varscan2
- ROPN1L | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 208/491 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56874362; called by muse, mutect2, varscan2
- RP1 | c.5020G>A p.D1674N | Missense Mutation (SNP) | VAF 185/399 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.462); catalogued as COSV55126970; called by muse, mutect2, varscan2
- RP1L1 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 303/629 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1339683035; called by muse, mutect2, varscan2
- RP1L1 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 264/623 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV101223369; called by muse, varscan2
- RSBN1 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 298/565 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54731075; called by muse, mutect2, varscan2
- RSPH6A | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 385/800 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574083; called by muse, mutect2, varscan2
- RTL3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 376/609 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs754780962, COSV100329782, COSV58183264; called by muse, mutect2, varscan2
- RYR1 | c.7210G>A p.E2404K | Missense Mutation (SNP) | VAF 245/561 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.27); catalogued as rs111364296, CM091767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.9020A>G p.N3007S | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1263831859; called by muse, mutect2, varscan2
- RYR1 | c.11090C>T p.P3697L | Missense Mutation (SNP) | VAF 188/454 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1396944765, COSV62098729; called by muse, varscan2
- SALL1 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 247/369 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV51765791; called by muse, mutect2, varscan2
- SAMD9 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 149/398 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1159455564; called by muse, mutect2, varscan2
- SAV1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 329/600 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs757631264; called by muse, mutect2, varscan2
- SBF1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 309/711 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62371027; called by muse, mutect2, varscan2
- SBSN | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 346/687 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101510040; called by muse, mutect2, varscan2
- SCARA5 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 245/522 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs752998049, COSV61572090, COSV61574497; called by muse, mutect2, varscan2
- SCGB3A2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 174/463 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57023891; called by muse, mutect2, varscan2
- SCN11A | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1403716541, COSV56565083; called by muse, mutect2, varscan2
- SCN11A | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 210/502 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56571409; called by muse, mutect2, varscan2
- SCN11A | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 146/598 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs1191368962, COSV100181967; called by muse, varscan2
- SCN1A | c.5735G>A p.R1912Q (on ENST00000303395 / NM_001202435.3; = p.R1901Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/359 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs373896263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 298/313 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV71125897; called by muse, mutect2, varscan2
- SCN5A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 278/585 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as COSV61116597; called by muse, mutect2, varscan2
- SCUBE1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 287/620 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as rs780067935, COSV62611441; called by muse, mutect2, varscan2
- SDHA | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 138/311 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); catalogued as COSV53766318, COSV53770526; called by muse, mutect2, varscan2
- SEMA3A | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.814); catalogued as rs1487309678; called by muse, mutect2, varscan2
- SERPINI2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 146/354 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217333684; called by muse, mutect2
- SETD1B | c.4760C>T p.P1587L | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1419095887, COSV57354738; called by muse, mutect2, varscan2
- SFPQ | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 303/588 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100599470; called by muse, mutect2, varscan2
- SGCZ | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601802, COSV65998392, COSV66047381; called by muse, mutect2, varscan2
- SH2B3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 390/731 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs933970612; called by muse, mutect2, varscan2
- SHANK2 | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 115/345 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV99576785; called by muse, mutect2, varscan2
- SHISA9 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 147/241 reads (61%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV69633146, COSV69644113; called by muse, mutect2, varscan2
- SHISA9 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 369/534 reads (69%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as rs1436328307; called by muse, mutect2, varscan2
- SIGLEC11 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 430/859 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.411); catalogued as rs550434699, COSV70221929; called by muse, mutect2, varscan2
- SIRPB1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54374122; called by muse, mutect2
- SLAMF8 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 399/768 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs868712155; called by muse, mutect2, varscan2
- SLC12A3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 203/305 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs780461639, CM121286; called by muse, mutect2, varscan2
- SLC17A1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 209/575 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752970228, COSV99766086; called by muse, mutect2, varscan2
- SLC17A3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs146416795; called by muse, mutect2, varscan2
- SLC17A6 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 133/518 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV99581498; called by muse, mutect2, varscan2
- SLC22A24 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 124/214 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1208836445; called by muse, mutect2, varscan2
- SLC26A6 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 260/537 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56571293; called by muse, mutect2, varscan2
- SLC27A6 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52488856; called by muse, mutect2, varscan2
- SLC2A14 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 178/209 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746537796; called by muse, mutect2, varscan2
- SLC2A14 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 180/212 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs780109041, COSV61586144, COSV61588360; called by muse, mutect2, varscan2
- SLC30A3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 84/308 reads (27%) | catalogued as COSV51988263; called by muse, mutect2, varscan2
- SLC35A4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 252/551 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as rs1488503931; called by muse, mutect2, varscan2
- SLC38A1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 150/273 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV67063435; called by muse, mutect2, varscan2
- SLC38A4 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56964769; called by muse, mutect2, varscan2
- SLC38A4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 221/390 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56964792; called by muse, mutect2, varscan2
- SLC38A5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 268/287 reads (93%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV58335440; called by muse, mutect2, varscan2
- SLC39A6 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 139/275 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52368024; called by muse, mutect2, varscan2
- SLC5A4 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 163/394 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs780445431, COSV99832085; called by muse, mutect2, varscan2
- SLC6A1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 203/448 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55116273; called by muse, varscan2
- SLC6A17 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 495/893 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs141398428; called by muse, mutect2, varscan2
- SLC6A8 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 180/758 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99466266; called by muse, mutect2, varscan2
- SLC8A3 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 244/456 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373933717; called by muse, mutect2, varscan2
- SLC9C1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV59885674; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SLX4IP | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 135/319 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs755713479, COSV57947634; called by muse, mutect2, varscan2
- SMC1B | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 207/434 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as rs1162326927; called by muse, mutect2, varscan2
- SNAPC4 | c.3374C>T p.P1125L | Missense Mutation (SNP) | VAF 306/660 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs777913079; called by muse, varscan2
- SNCAIP | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 180/401 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54404148; called by muse, mutect2, varscan2
- SNCAIP | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV54403378; called by muse, mutect2, varscan2
- SNCAIP | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 207/449 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs773604913, COSV54403432; called by muse, mutect2, varscan2
- SOGA1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 145/352 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs181256903, COSV52922181; called by muse, mutect2, varscan2
- SORCS3 | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 218/247 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63793627; called by muse, mutect2, varscan2
- SORL1 | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 78/270 reads (29%) | catalogued as COSV52752740; called by muse, mutect2, varscan2
- SORL1 | c.4210G>A p.G1404R | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.489); catalogued as rs1451714828; called by muse, varscan2
- SOX14 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 377/867 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV60162738; called by muse, mutect2, varscan2
- SPAM1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 218/404 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV56141005; called by muse, mutect2, varscan2
- SPATA4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 100/125 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54589530; called by muse, mutect2, varscan2
- SPDYE5 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1554483405; called by muse, varscan2
- SPTA1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 198/516 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63754117, COSV63759555; called by muse, mutect2, varscan2
- SPTBN4 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 285/668 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1488394403; called by muse, mutect2, varscan2
- SRCAP | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 278/415 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99349878; called by muse, mutect2, varscan2
- SRGAP3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64530320; called by muse, mutect2, varscan2
- SRMS | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 166/844 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs56053583; called by muse, mutect2, varscan2
- SRRM4 | c.1763_1786del p.R588_S595del | In Frame Del (DEL) | VAF 254/594 reads (43%) | catalogued as rs778154280; called by mutect2, varscan2
- SRSF11 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 211/561 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs750684163; called by muse, mutect2, varscan2
- SRSF2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 308/700 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV57971542; called by muse, varscan2
- SSC5D | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 331/747 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs865785650; called by muse, mutect2, varscan2
- SST | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 251/610 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); catalogued as COSV55030327; called by muse, mutect2, varscan2
- SSX2IP | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 245/442 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60553697; called by muse, mutect2, varscan2
2,120 further variants in this file (1,014 protein-altering or splice-affecting, 990 silent, 116 other) are not listed here.
